Somatic mutation profile of tumor specimen MP2PRT-PAUREZ-TMP1-A (aliquot MP2PRT-PAUREZ-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUREZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,639 days).
Specimen MP2PRT-PAUREZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53a5c015-4cc1-4677-bdf4-cfa70aa3fa88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUREZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUREZ-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d2af3a4-e7fd-4940-be16-13b66abe3a77

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Nonsense Mutation 4, Splice Site 2, In Frame Ins 2, 5'Flank 1, In Frame Del 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 115/326 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHD7 | c.5211-1G>T p.X1737_splice | Splice Site (SNP) | VAF 15/259 reads (6%) | catalogued as CS126676, COSV71108890; called by muse, mutect2
- GJB3 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 196/532 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527683895, COSV100974043; called by muse, mutect2, varscan2
- MAP3K21 | c.2278C>T p.R760* | Nonsense Mutation (SNP) | VAF 198/502 reads (39%) | catalogued as rs373332852, COSV64041911; called by muse, mutect2
- PIK3CB | c.972+1G>C p.X324_splice | Splice Site (SNP) | VAF 10/144 reads (7%) | catalogued as COSV56688196; called by muse, mutect2
- POLR2B | c.2702C>T p.T901M | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1271379137; called by muse, mutect2, varscan2
- RELN | c.10357C>T p.R3453* | Nonsense Mutation (SNP) | VAF 103/263 reads (39%) | catalogued as rs139326865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMPRSS6 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 262/591 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs780451143; called by muse, mutect2, varscan2
- USP17L7 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 150/794 reads (19%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.506); catalogued as rs772555466; called by muse, mutect2, varscan2
- ARIH2 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 215/462 reads (47%) | called by muse, mutect2, varscan2
- BMPER | c.1007G>A p.C336Y | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A1 | c.1151G>A p.R384K | Missense Mutation (SNP) | VAF 242/511 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EP300 | c.5197_5202delinsGC p.L1733Afs*28 | Frame Shift Del (DEL) | VAF 138/335 reads (41%) | called by pindel, varscan2*
- HRNR | c.5301C>A p.Y1767* | Nonsense Mutation (SNP) | VAF 102/542 reads (19%) | called by muse, mutect2, varscan2
- IGKV1-6 | c.340_351delinsGAC p.Y114_P117delinsD | In Frame Del (DEL) | VAF 13/63 reads (21%) | called by pindel, varscan2*
- IGLV4-69 | c.358_359insTCGCC | In Frame Ins (INS) | VAF 72/168 reads (43%) | called by mutect2, varscan2
- IGLV4-69 | c.359delinsTCGCCT | In Frame Ins (INS) | VAF 84/179 reads (47%) | called by mutect2*, pindel, varscan2*
- LHX3 | c.501G>T p.K167N (on ENST00000371748 / NM_178138.6; = p.K172N on NM_014564.5) | Missense Mutation (SNP) | VAF 286/921 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- POP5 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 115/315 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- SMPDL3A | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UQCC1 | c.898T>C p.*300Rext*48 | Nonstop Mutation (SNP) | VAF 140/286 reads (49%) | called by muse, mutect2, varscan2
- ZNF814 | c.99T>G p.S33R | Missense Mutation (SNP) | VAF 190/443 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- ASB2 | c.1617G>A p.K539= | Silent (SNP) | VAF 181/401 reads (45%) | called by muse, mutect2, varscan2
- CCDC146 | c.1063A>C p.R355= | Silent (SNP) | VAF 121/232 reads (52%) | called by muse, mutect2, varscan2
- NPAS3 | c.2685G>A p.T895= (on ENST00000356141 / NM_001164749.2; = p.T863= on NM_022123.3) | Silent (SNP) | VAF 247/502 reads (49%) | catalogued as rs1261208719; called by muse, mutect2, varscan2
- PCDHGB3 | c.1533C>T p.S511= | Silent (SNP) | VAF 297/697 reads (43%) | catalogued as rs750914672, COSV53987983, COSV53996649; called by muse, mutect2, varscan2
- PTCHD4 | c.672G>A p.R224= | Silent (SNP) | VAF 181/424 reads (43%) | called by muse, mutect2, varscan2
- SLC6A15 | c.1500C>A p.I500= | Silent (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- ZIC1 | c.48C>A p.T16= | Silent (SNP) | VAF 274/539 reads (51%) | called by muse, mutect2, varscan2
- EBNA1BP2 | chr1:43172315 C>T | 5'Flank (SNP) | VAF 200/451 reads (44%) | catalogued as COSV52540034; called by muse, mutect2, varscan2
